Gene-level copy-number profile of tumor specimen HTMCP-03-06-02427-01A from CGCI case HTMCP-03-06-02427, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 43.8 years (15,987 days).
Specimen HTMCP-03-06-02427-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 46c46275-6659-44fb-814b-9738601495df.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02427-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/c333b4fe-14a6-4baa-8796-acec9b113152

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 548; copy number 2: 5,240; copy number 3: 10,885; copy number 4: 30,693; copy number 5: 8,228; copy number 6: 1,831; copy number 7: 178; copy number 8: 573; copy number 9: 44; copy number 10: 167; copy number 13: 4; copy number 26: 2.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,208,082–141,208,376, 1 gene (within-gene range 0–4): RPS16P3.
- chr8:42,271,302–42,332,460, 1 gene: IKBKB.
- chr8:42,341,767–42,342,634, 1 gene (within-gene range 0–2): RPL5P23.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 217 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,928,422–91,843,802, 43 genes, copy number 9–13: IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1, LSP1P4, RNA5SP100, DRD5P1, AC027612.2, NKAIN1P2, AC027612.1, KMT5AP2, AC027612.3, GGT8P, IGKV1OR2-1, ABCD1P5.
- chr18:109,065–4,455,307, 92 genes, copy number 10–26 (within-gene range 4–26) (broad region; genes not listed).
- chr19:18,990,888–20,039,505, 54 genes, copy number 10: SUGP2, ARMC6, SLC25A42, TMEM161A, MEF2B, BORCS8-MEF2B, BORCS8, RFXANK, NR2C2AP, NCAN, RNU6-1028P, AC138430.1, HAPLN4, AC138430.2, TM6SF2, SUGP1, MAU2, GATAD2A, AC092067.1, MIR640, TSSK6, NDUFA13, AC011448.1, YJEFN3, CILP2, PBX4, PHF5CP, AC002306.1, LPAR2, GMIP, ATP13A1, ZNF101, AC011458.2, AC011458.1, ZNF14, AC011477.6, AC011477.7, AC011477.5, LINC00663, AC011477.8, AC011477.3, AC011477.4, ZNF56, ZNF506, AC011477.1, BNIP3P9, ZNF253, BNIP3P10, AC011477.2, ZNF93, AC007204.1, AC007204.2, ZNF682, AC006539.2.
- chr19:22,391,019–22,623,971, 19 genes, copy number 9: ZNF98, AC011516.1, BNIP3P32, AC025811.1, BNIP3P33, ZNF209P, AC004004.1, AC011467.6, AC011467.1, LINC01233, RNU6-1179P, AC011467.5, GOLGA2P9, RN7SL860P, AC011467.3, AC011467.4, RAD54L2P1, LINC01785, AC011467.2.
- chr21:26,158,091–26,845,409, 9 genes, copy number 9 (within-gene range 7–9): AP001439.1, AP000229.1, RNU6-926P, AP001595.1, AP001596.1, CYYR1-AS1, AP001596.2, CYYR1, ADAMTS1.

Autosomal genes at a single copy (total copy number 1): 548. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
